Somatic mutation profile of tumor specimen TCGA-XF-AAN4-01A (aliquot TCGA-XF-AAN4-01A-11D-A42E-08) from TCGA case TCGA-XF-AAN4, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 77.5 years (28,302 days).
Specimen TCGA-XF-AAN4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 616ce6e0-1b21-4220-a026-9ae42a7a383d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAN4-10A (Blood Derived Normal), aliquot TCGA-XF-AAN4-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff6a283c-634d-462d-9d22-fe6122523b3b

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, RNA 2, Frame Shift Del 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs373295539, COSV53996181; called by muse, mutect2
- APLP1 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.106); catalogued as COSV55704908; called by muse, mutect2
- CPT1A | c.1944G>T p.M648I | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1042056896, COSV55757890; called by muse, mutect2
- DDR2 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as rs202091759, COSV63370049, COSV63370496, COSV63372203; called by muse, mutect2, varscan2
- DNAH7 | c.8977C>G p.P2993A | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56754782, COSV56762117, COSV56772823; called by muse, mutect2
- FGFR4 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV52805880; called by muse, mutect2, varscan2
- GNPAT | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64153756; called by muse, mutect2
- HTR2C | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.956); catalogued as COSV52217204; called by muse, mutect2
- LINGO2 | c.1729A>G p.I577V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as COSV58061357; called by muse, mutect2, varscan2
- LRRK2 | c.1586A>G p.K529R | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1480540142, COSV54159471; called by muse, mutect2
- LY75 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.136); catalogued as COSV55108485; called by muse, mutect2
- MAGEA12 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); catalogued as COSV63294998; called by muse, mutect2
- MTA2 | c.1534C>G p.L512V | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1244376172, COSV53470764; called by muse, mutect2
- MYO1C | c.1889A>T p.D630V (on ENST00000648651 / NM_001080779.2; = p.D595V on NM_033375.5) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100704401; called by muse, mutect2
- PAPPA | c.1358A>G p.H453R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV60286985; called by muse, varscan2
- PCDHB4 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52023523, COSV52024096; called by muse, mutect2
- RP1 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV55117179, COSV55120513; called by muse, mutect2
- SCG2 | c.1772T>C p.M591T | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV59540774; called by muse, mutect2
- SEMA3C | c.2112G>A p.M704I | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54849932; called by muse, mutect2
- SPAST | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100188589; called by muse, mutect2
- SYNE2 | c.4483C>G p.P1495A | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.197); catalogued as COSV100647491, COSV59947497, COSV59957025; called by muse, mutect2
- TAF1B | c.695C>G p.S232* | Nonsense Mutation (SNP) | VAF 5/148 reads (3%) | catalogued as COSV99722219; called by muse, mutect2
- TENM2 | c.1894G>C p.E632Q (on ENST00000518659 / NM_001122679.2; = p.E400Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV69134889; called by muse, mutect2
- TIMELESS | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV57512990; called by muse, mutect2
- TTK | c.2131A>G p.I711V | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV57884890; called by muse, mutect2
- USP34 | c.5491C>A p.Q1831K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV68403141; called by muse, mutect2
- IGHV1-46 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2
- LMO4 | c.332del p.K111Sfs*40 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- COL6A2 | c.1689T>A p.P563= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV56009913; called by mutect2, varscan2
- LILRA1 | c.1200A>G p.S400= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV52182289; called by muse, mutect2
- SH3D21 | c.2031G>A p.P677= (on ENST00000453908 / NM_001162530.2; = p.P566= on NM_024676.5) | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- SLC24A2 | c.84T>C p.Y28= | Silent (SNP) | VAF 29/151 reads (19%) | catalogued as rs747196973, COSV53868658; called by muse, mutect2, varscan2
- TMEM150B | c.105C>A p.L35= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as COSV58594038; called by muse, mutect2
- UBASH3B | c.840C>T p.F280= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV52497487; called by muse, mutect2
- ACSBG1 | c.-1G>C | 5'UTR (SNP) | VAF 6/126 reads (5%) | catalogued as rs1328685613, COSV99357482; called by muse, mutect2
- C9orf163 | n.1293G>C | RNA (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- XIST | n.7507C>G | RNA (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
